Gene-level copy-number profile of tumor specimen TCGA-KU-A6H7-01A from TCGA case TCGA-KU-A6H7, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 55.6 years (20,314 days).
Specimen TCGA-KU-A6H7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.c1e934f0-aca5-4390-8983-a63104e531e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KU-A6H7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/34a22b3e-54c9-4666-a8ea-d037199e9ac9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 10,718; copy number 2: 45,500; copy number 3: 3,518; copy number 4: 42; copy number 5: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KU-A6H7-01A-11D-A31K-01): tumor purity 0.54, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–1): PTEN.
- chr10:87,945,502–87,994,695, 2 genes: RPL11P3, AC063965.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:1,980,290–2,193,624, 1 gene, copy number 5 (within-gene range 2–5): SMARCA2.
- chr9:2,162,763–2,229,241, 2 genes, copy number 5: RNU2-25P, RN7SL592P.
- chr9:3,181,342–3,200,445, 1 gene, copy number 5: LINC01231.
- chr9:5,123,880–5,629,748, 14 genes, copy number 5 (within-gene range 2–5): INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1.

Autosomal genes at a single copy (total copy number 1): 10,718. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
